Somatic mutation profile of tumor specimen C3L-03497-54 (aliquot CPT0230630002) from CPTAC case C3L-03497, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 60.0 years (21,911 days).
Specimen C3L-03497-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c00c1c8-b29e-4ee5-bd17-c5c1022aed8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03497-51 (Buccal Cell Normal), aliquot CPT0230660001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc8fad5c-33c3-4249-a4f7-f7f650f64a6b

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 154/364 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, varscan2
- INPP5A | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs144055417; called by muse, mutect2, varscan2
- PCDHB4 | c.796A>G p.R266G | Missense Mutation (SNP) | VAF 111/316 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PSD | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STAG2 | c.2581A>T p.R861* | Nonsense Mutation (SNP) | VAF 97/113 reads (86%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1094676 G>A | 3'Flank (SNP) | VAF 56/160 reads (35%) | called by muse, varscan2
